Somatic mutation profile of tumor specimen 7c7ce2d7-6c8a-424e-8e6c-d14ad1 (aliquot 7c7ce2d7-6c8a-424e-8e6c-d14ad1_D6_1) from CPTAC case 15OV001, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 7c7ce2d7-6c8a-424e-8e6c-d14ad1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ba71160-cb6b-4064-a872-a7f74466d453.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 60daddeb-d877-481a-9901-883bb8 (Blood Derived Normal), aliquot 60daddeb-d877-481a-9901-883bb8_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9308d6e1-51f0-4092-a0bf-55db0684fa29

The open-access MAF lists 529 somatic variants for this specimen: 336 protein-altering or splice-affecting, 117 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 255, Silent 117, Frame Shift Del 46, Intron 38, 3'UTR 15, RNA 12, Frame Shift Ins 11, Nonsense Mutation 11, Splice Site 8, 5'UTR 6, In Frame Del 3, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HEXA | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 26/363 reads (7%) | catalogued as rs786204585, CM113520, COSV51507538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 25/191 reads (13%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- PIGV | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 55/434 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149690056; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.17_18del p.K6Rfs*4 | Frame Shift Del (DEL) | VAF 26/279 reads (9%) | catalogued as rs121913290; ClinVar: pathogenic; called by pindel, varscan2
- TGFBR2 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 48/375 reads (13%) | catalogued as rs863223852, CM063204, COSV55443474; ClinVar: pathogenic / uncertain significance; called by muse, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 87/727 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC1 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 34/506 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs546292624, COSV60680897; called by muse, mutect2
- ABCF1 | c.1160G>A p.R387Q (on ENST00000326195 / NM_001025091.2; = p.R349Q on NM_001090.3) | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs866488428; called by muse, mutect2
- ABLIM3 | c.364A>G p.T122A | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58644971; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM33 | c.2366C>A p.P789H | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV99051899; called by muse, mutect2
- ADAMTS1 | c.1589A>G p.D530G | Missense Mutation (SNP) | VAF 11/257 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53173688; called by muse, mutect2
- ADAMTS10 | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 72/780 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as rs1027053190; called by muse, mutect2
- ADCK5 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 35/558 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.435); catalogued as rs1554861425, COSV58235722; called by muse, mutect2
- ANGPTL4 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 58/578 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs1420376915; called by muse, mutect2
- ANK1 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 45/414 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs758845076; called by muse, mutect2, varscan2
- ANKH | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.683); catalogued as rs754903658; called by muse, mutect2, varscan2
- ANKRD13B | c.1279C>A p.L427I | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs1270159551; called by muse, mutect2
- APLP2 | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs952447990; called by muse, mutect2, varscan2
- ARID1A | c.671del p.P224Rfs*8 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as rs1462224784; called by mutect2, varscan2
- ARMC12 | c.952T>C p.Y318H (on ENST00000373866 / NM_001286574.2; = p.Y345H on NM_145028.5) | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.087); catalogued as rs767422977; called by muse, mutect2, varscan2
- ARMCX5 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1405965221, COSV55766354; called by muse, mutect2
- ASB2 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs113529772, COSV60111246, COSV60113216; called by muse, mutect2, varscan2
- BPIFB6 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.372); catalogued as rs79809934, COSV62755422, COSV62757447; called by muse, mutect2
- BTBD19 | c.698T>A p.L233Q | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV69767962; called by muse, mutect2
- BTNL2 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 59/531 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs532711374; called by muse, mutect2, varscan2
- C5orf49 | c.428A>G p.H143R | Missense Mutation (SNP) | VAF 41/301 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as COSV100602239; called by muse, mutect2, varscan2
- CAB39L | c.502T>A p.F168I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100759572; called by muse, mutect2, varscan2
- CACNA1H | c.5750G>A p.R1917H | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs575944941, COSV99326613; called by muse, mutect2
- CAMKK1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 38/334 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764993423, COSV50115099; called by muse, mutect2, varscan2
- CAPRIN1 | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1171575337, COSV58221596; called by muse, mutect2
- CARD9 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs774571551, COSV59998868; ClinVar: uncertain significance; called by muse, mutect2
- CASR | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV56140310; called by muse, mutect2
- CCDC85C | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1157471110; called by muse, mutect2
- CD1D | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV63809439; called by muse, mutect2, varscan2
- CD93 | c.1307del p.G436Afs*152 | Frame Shift Del (DEL) | VAF 26/225 reads (12%) | catalogued as rs779465056; called by mutect2, varscan2
- CDCA2 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs1314288211, COSV57944236; called by muse, mutect2, varscan2
- CDH10 | c.1428del p.F476Lfs*2 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | catalogued as rs1176348287; called by mutect2, pindel, varscan2
- CDK11B | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1462668002; called by muse, mutect2, varscan2
- CDK20 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 39/332 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs144310084; called by muse, mutect2, varscan2
- CHD4 | c.3274C>T p.R1092W (on ENST00000357008 / NM_001363606.2; = p.R1105W on NM_001273.5) | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58898720; called by muse, mutect2, varscan2
- CR2 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200595124; called by muse, mutect2, varscan2
- CRAT | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 57/498 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs776507175, COSV58876854; called by muse, mutect2, varscan2
- CSNK1A1L | c.690del p.K230Nfs*31 | Frame Shift Del (DEL) | VAF 34/320 reads (11%) | catalogued as rs369743261; called by mutect2, varscan2
- CX3CL1 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as rs374124184; called by muse, mutect2, varscan2
- DDX24 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.121); catalogued as rs145620061; called by muse, mutect2, varscan2
- DGKB | c.2089G>A p.V697I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.029); catalogued as COSV99340093; called by muse, mutect2, varscan2
- DLAT | c.342del p.E115Rfs*10 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as rs782180715; called by mutect2, varscan2
- DNHD1 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV54436417; called by muse, mutect2, varscan2
- DPP8 | c.1706G>A p.R569H (on ENST00000341861 / NM_001320875.2; = p.R553H on NM_017743.6) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.803); catalogued as rs759901599; called by muse, mutect2, varscan2
- E2F1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs762296081, COSV55777414; called by muse, mutect2, varscan2
- ENTPD6 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs1017811642, COSV100737107; called by muse, mutect2, varscan2
- ENTPD6 | c.461A>G p.Q154R | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as rs765173082; called by muse, mutect2, varscan2
- ERICH4 | c.64del p.Q22Rfs*3 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as rs567420399; called by mutect2, pindel, varscan2
- F5 | c.2677C>T p.H893Y | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1557916192; called by muse, mutect2
- F7 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 72/637 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.814); catalogued as rs769476482; called by muse, mutect2, varscan2
- FAM135B | c.1880A>G p.K627R | Missense Mutation (SNP) | VAF 58/360 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs369582133; called by muse, mutect2, varscan2
- FAM160B2 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 22/287 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs771300488; called by muse, mutect2
- FAM83G | c.2404G>A p.G802S | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs200106667, COSV58760362; called by muse, mutect2, varscan2
- FCGR2A | c.197G>A p.R66H (on ENST00000271450 / NM_001136219.3; = p.R65H on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/480 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750989159, COSV54838318; called by muse, mutect2, varscan2
- FEM1C | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.111); catalogued as rs766075601; called by muse, mutect2
- GAD2 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs1429001547, COSV99394428; called by muse, mutect2
- GATA3 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 52/363 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs747477962; called by muse, mutect2, varscan2
- GCKR | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 38/289 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs772997882, COSV53107101; called by muse, mutect2, varscan2
- GGTLC2 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as rs147760451; called by muse, mutect2, varscan2
- GLT6D1 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs756561670, COSV65627142; called by mutect2, varscan2
- GNAS | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 17/386 reads (4%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.009); catalogued as COSV99047797; called by muse, mutect2
- GRIP2 | c.908C>T p.P303L (on ENST00000619221; = p.P206L on NM_001080423.4) | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs1004522653; called by muse, mutect2, varscan2
- GUCY2D | c.2788G>A p.A930T | Missense Mutation (SNP) | VAF 22/441 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1370972064; called by muse, mutect2
- GUK1 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs745590424; called by muse, mutect2
- HEPH | c.3419G>A p.R1140Q (on ENST00000343002; = p.R873Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/427 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs757725630, COSV57972226; called by muse, mutect2
- HEXD | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370204851; called by muse, mutect2
- HIRA | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as rs769555605, COSV99600796; called by muse, mutect2, varscan2
- HSF4 | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779043988; called by muse, mutect2, varscan2
- HSPG2 | c.11156G>A p.R3719Q | Missense Mutation (SNP) | VAF 30/512 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.818); catalogued as rs78280998; called by muse, mutect2
- HSPG2 | c.9269G>A p.R3090H | Missense Mutation (SNP) | VAF 67/654 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs371570424; called by muse, mutect2, varscan2
- HTR2C | c.724C>A p.R242S | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV99349242; called by muse, mutect2, varscan2
- IBSP | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773567537, COSV56896405; called by muse, mutect2, varscan2
- IGHV6-1 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 61/560 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs782100113; called by muse, mutect2, varscan2
- IL18BP | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.288); catalogued as rs770102511, COSV52621001; called by muse, mutect2
- INTS2 | c.2971C>T p.R991* | Nonsense Mutation (SNP) | VAF 18/142 reads (13%) | catalogued as rs748698616, COSV99247567; called by muse, mutect2, varscan2
- IRS2 | c.3397G>A p.A1133T | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65478911; called by muse, mutect2
- ITGA9 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs376199202, COSV53238804; called by muse, mutect2
- ITGB4 | c.4798G>A p.V1600M | Missense Mutation (SNP) | VAF 84/656 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771612802; called by muse, mutect2, varscan2
- JPH1 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 34/337 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773593138, COSV100646600; called by muse, mutect2
- JPH1 | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV60611831; called by muse, mutect2, varscan2
- KBTBD7 | c.1076A>G p.Y359C | Missense Mutation (SNP) | VAF 98/900 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs766061928, COSV101068047; called by muse, mutect2, varscan2
- KIF1B | c.3158G>A p.R1053H (on ENST00000377086 / NM_001365952.1; = p.R1007H on NM_015074.3) | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs969289278, COSV55815967; called by muse, mutect2
- KIF4B | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 34/357 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs200942753; called by muse, mutect2, varscan2
- KMT2D | c.4223G>A p.C1408Y | Missense Mutation (SNP) | VAF 23/238 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56421577, COSV56461887; called by muse, mutect2
- LCP2 | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 5/92 reads (5%) | catalogued as COSV50457059; called by muse, mutect2
- LOXHD1 | c.6582G>A p.M2194I (on ENST00000642948; = p.M2132I on NM_144612.7) | Missense Mutation (SNP) | VAF 98/920 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.242); catalogued as rs1395748994; called by muse, mutect2, varscan2
- LOXHD1 | c.4774A>G p.S1592G | Missense Mutation (SNP) | VAF 26/347 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.561); catalogued as rs1471105046; called by muse, mutect2
- MLLT6 | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 15/273 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs1319765006; called by muse, mutect2
- MLXIP | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 38/342 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1448835327; called by muse, mutect2, varscan2
- MMP19 | c.1475G>A p.G492D | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV59453124; called by muse, varscan2
- MRPL38 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 61/456 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs766019304, COSV53932438; called by mutect2, varscan2
- MUC16 | c.28289dup p.N9430Kfs*27 | Frame Shift Ins (INS) | VAF 22/204 reads (11%) | catalogued as rs774904775; called by mutect2, varscan2
- MYO15A | c.1562del p.P521Rfs*108 | Frame Shift Del (DEL) | VAF 18/172 reads (10%) | catalogued as rs761219220; called by mutect2, varscan2
- MYO5B | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 67/589 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs772794033, COSV53225182; called by muse, mutect2, varscan2
- MYO7B | c.5577_5579del p.F1860del | In Frame Del (DEL) | VAF 17/169 reads (10%) | catalogued as rs753217299; called by pindel, varscan2
- NAT1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as rs760970670; called by muse, mutect2, varscan2
- NCEH1 | c.143C>T p.A48V (on ENST00000538775; = p.A16V on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/352 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1414584773; called by muse, mutect2
- NFASC | c.2683C>T p.R895C (on ENST00000339876 / NM_001378329.1; = p.R998C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as rs747420515, COSV58360694; called by muse, mutect2, varscan2
- NOTCH3 | c.5323G>A p.A1775T | Missense Mutation (SNP) | VAF 65/388 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as rs139983430; called by muse, mutect2, varscan2
- NPR2 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 78/480 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs766118843, COSV61312494, COSV61315234; called by muse, mutect2, varscan2
- NT5C2 | c.516dup p.T173Yfs*2 | Frame Shift Ins (INS) | VAF 12/80 reads (15%) | catalogued as rs1348834719; called by mutect2, varscan2
- OLFM4 | c.1363dup p.Y455Lfs*4 | Frame Shift Ins (INS) | VAF 20/176 reads (11%) | catalogued as rs1286448354; called by mutect2, pindel
- OR6T1 | c.265del p.D89Ifs*19 | Frame Shift Del (DEL) | VAF 34/340 reads (10%) | catalogued as COSV58305844; called by mutect2, pindel
- PAK4 | c.565del p.Q189Sfs*180 | Frame Shift Del (DEL) | VAF 11/116 reads (9%) | catalogued as rs1217359611; called by mutect2, pindel, varscan2
- PCDHB2 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 56/654 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.187); catalogued as COSV99165349; called by muse, mutect2
- PCDHGA1 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 87/734 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.035); catalogued as rs371049984; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 17/147 reads (12%) | catalogued as COSV61618667; called by mutect2, varscan2
- PIGQ | c.1612C>T p.R538C (on ENST00000026218 / NM_148920.3; = p.G558= on NM_004204.5) | Missense Mutation (SNP) | VAF 54/380 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs760639555, COSV50315164; ClinVar: likely benign; called by muse, mutect2, varscan2
- PKD1L2 | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1302941787; called by muse, mutect2, varscan2
- PLA2G4E | c.2564C>T p.A855V | Missense Mutation (SNP) | VAF 50/426 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as rs1020451485; called by muse, mutect2, varscan2
- PLEKHD1 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as rs1205253254; called by muse, mutect2
- PLOD1 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 64/484 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1428519006, COSV52148789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA2 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1474889326; called by muse, mutect2
- PLXNA3 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 19/361 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1557205695; called by muse, mutect2
- PNLIPRP2 | c.1344-1G>T p.X448_splice (on ENST00000611850; = p.X449_splice on NM_005396.5) | Splice Site (SNP) | VAF 15/126 reads (12%) | catalogued as COSV53945912; called by muse, mutect2, varscan2
- PPP1R10 | c.930del p.V311Yfs*79 | Frame Shift Del (DEL) | VAF 16/148 reads (11%) | catalogued as rs746108087; called by mutect2, varscan2
- PPP1R7 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.167); catalogued as rs780500587, COSV52144193; called by muse, mutect2, varscan2
- PRKDC | c.7384G>A p.V2462I | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776319051; called by muse, mutect2, varscan2
- PRR12 | c.469G>A p.A157T (on ENST00000615927; = p.A978T on NM_020719.3) | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs752530502, COSV101330792; called by muse, mutect2, varscan2
- PRSS33 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53450858; called by muse, mutect2
- PRSS41 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 32/293 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs1407464493, COSV101294309; called by muse, mutect2, varscan2
- PSAP | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 54/631 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.363); catalogued as rs376639872; called by muse, mutect2
- PXDN | c.2828G>A p.R943Q | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.545); catalogued as rs779860789, COSV53227068, COSV99412218; called by muse, mutect2, varscan2
- RC3H2 | c.3169A>G p.I1057V | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.456); catalogued as rs1162604433; called by muse, mutect2, varscan2
- REXO1 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV50087460; called by muse, mutect2, varscan2
- REXO1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs770944469; called by muse, mutect2, varscan2
- RHBDL1 | c.733G>A p.A245T (on ENST00000219551 / NM_001318733.2; = p.A180T on NM_001278720.2) | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV99556053; called by muse, mutect2
- RNF40 | c.2599G>A p.A867T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs897850895; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 17/114 reads (15%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNH1 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 46/478 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.451); catalogued as rs762505688, COSV100596678; called by muse, mutect2
- RP1L1 | c.3209T>C p.V1070A | Missense Mutation (SNP) | VAF 61/287 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs746579166; called by muse, mutect2, varscan2
- RPTOR | c.1039T>C p.F347L | Missense Mutation (SNP) | VAF 14/285 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as COSV60821779; called by muse, mutect2
- SATB2 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 29/338 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV53478415; called by muse, mutect2
- SFXN4 | c.360G>A p.T120= | Splice Region (SNP) | VAF 13/126 reads (10%) | catalogued as rs920028881, COSV57460185; called by muse, mutect2, varscan2
- SHROOM2 | c.2680C>T p.R894C | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs370597896, COSV66605102; called by muse, mutect2, varscan2
- SHROOM4 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 51/454 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192380439, COSV56792766; called by muse, mutect2, varscan2
- SIK3 | c.704G>A p.G235E (on ENST00000445177 / NM_001366686.2; = p.G241E on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415319949, COSV99408321; called by muse, mutect2
- SLC14A2 | c.2390C>T p.A797V | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs776377373, COSV99675635; called by muse, mutect2
- SNAI1 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54863766; called by muse, varscan2
- SNAPC4 | c.3874del p.V1292Cfs*115 | Frame Shift Del (DEL) | VAF 32/266 reads (12%) | catalogued as rs768556711; called by mutect2, pindel, varscan2
- SPATA31E1 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.162); catalogued as rs754686978, COSV57790205; called by muse, mutect2
- SPEG | c.6973G>A p.E2325K | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as rs1224823615, COSV56665068; called by muse, mutect2, varscan2
- SPG11 | c.3247C>A p.L1083M | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104380205; called by muse, mutect2
- SPIRE1 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs776709366; called by muse, mutect2
- SPTB | c.4597C>T p.R1533W | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.398); catalogued as rs140301241; called by muse, mutect2
- SPTY2D1 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200405595, COSV60473919; called by mutect2, varscan2
- SRF | c.1337G>A p.S446N | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs1412250002; called by muse, varscan2
- SSX5 | c.269G>A p.R90H (on ENST00000347757 / NM_175723.1; = p.R131H on NM_021015.4) | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs782483765, COSV61255908; called by muse, mutect2
- ST14 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 47/708 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs778216393; called by muse, mutect2
- STX8 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as rs762587055; called by mutect2, varscan2
- SYNE1 | c.14186C>T p.A4729V (on ENST00000367255 / NM_182961.4; = p.A4658V on NM_033071.3) | Missense Mutation (SNP) | VAF 47/391 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs749275993, COSV54909248; called by muse, mutect2, varscan2
- TECPR1 | c.2797G>A p.A933T | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1368685802, COSV65783352; called by muse, mutect2, varscan2
- TELO2 | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs749527552, COSV51981202; called by muse, mutect2
- TENM1 | c.3595G>A p.A1199T | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs143931463; called by muse, mutect2, varscan2
- THBS1 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs373429232; called by muse, mutect2, varscan2
- TJP2 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 17/192 reads (9%) | catalogued as COSV55268351; called by muse, mutect2
- TMEM260 | c.255T>G p.F85L | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs188596516; called by muse, mutect2
- TNN | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs760781433, COSV99511658; called by muse, mutect2, varscan2
- TSHZ1 | c.2548C>T p.R850C (on ENST00000580243 / NM_001308210.2; = p.R805C on NM_005786.6) | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs146587557, COSV59005134; called by muse, mutect2, varscan2
- TTC28 | c.1657C>T p.Q553* | Nonsense Mutation (SNP) | VAF 22/264 reads (8%) | catalogued as COSV67423208; called by muse, mutect2
- TTLL11 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs1477838078, COSV58644120; called by muse, mutect2, varscan2
- TTN | c.62167A>G p.K20723E (on ENST00000591111; = p.K13299E on NM_003319.4) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | PolyPhen probably damaging (0.994); catalogued as rs1426155742; called by muse, mutect2
- TUBGCP3 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.752); catalogued as rs781567938; called by muse, mutect2, varscan2
- UNC5B | c.1588G>A p.G530S | Missense Mutation (SNP) | VAF 59/457 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.029); catalogued as rs761845735, COSV100100836; called by muse, mutect2, varscan2
- UPF1 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1362041868, COSV53194365; called by muse, mutect2
- VPS28 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1554876052, COSV52873260; called by muse, mutect2, varscan2
- WBP1L | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs139434993, COSV64009961; called by muse, mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 30/254 reads (12%) | catalogued as rs746919573; called by mutect2, varscan2
- WWP2 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 20/137 reads (15%) | catalogued as COSV63123889; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 45/398 reads (11%) | catalogued as rs779864368; called by mutect2, varscan2
- ZC3H12A | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 66/556 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as rs370603018; called by muse, varscan2
- ZDHHC5 | c.1394A>G p.N465S | Missense Mutation (SNP) | VAF 49/507 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs369287219; called by muse, mutect2, varscan2
- ZMYND15 | c.1520_1523del p.K507Sfs*3 (on ENST00000433935 / NM_001136046.3; = p.K468Sfs*3 on NM_032265.2) | Frame Shift Del (DEL) | VAF 36/340 reads (11%) | catalogued as rs587777432; called by pindel, varscan2
- ZNF185 | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as rs782760720; called by muse, mutect2
- ZNF30 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 28/297 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as rs774762859; called by muse, mutect2
- ZNF416 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV52183729; called by muse, mutect2
- ZNF517 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs369684380; called by muse, varscan2
- ZNF573 | c.1348del p.T450Pfs*74 (on ENST00000536220 / NM_001172692.1; = p.T392Pfs*74 on NM_152360.3) | Frame Shift Del (DEL) | VAF 20/173 reads (12%) | catalogued as rs751020931; called by mutect2, pindel, varscan2
- ZNF575 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 34/403 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs778606721, COSV58564790; called by muse, mutect2
- ZNF697 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1188091083; called by muse, mutect2
- ZNFX1 | c.4463G>A p.R1488Q | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as rs111396903; called by muse, mutect2
- ABCB8 | c.1226del p.G409Efs*31 (on ENST00000297504 / NM_001282291.2; = p.G392Efs*31 on NM_007188.5) | Frame Shift Del (DEL) | VAF 19/164 reads (12%) | called by mutect2, pindel, varscan2
- ABCF1 | c.447T>G p.H149Q | Missense Mutation (SNP) | VAF 28/303 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2
- ACTN1 | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.616); called by muse, mutect2
- ADAMTS13 | c.1319dup p.T441Dfs*93 | Frame Shift Ins (INS) | VAF 28/279 reads (10%) | called by mutect2, pindel, varscan2
- AL645922.1 | c.3201dup p.E1068Rfs*6 | Frame Shift Ins (INS) | VAF 32/372 reads (9%) | called by mutect2, pindel
- ALOX5AP | c.55A>G p.S19G | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, varscan2
- ANKRD9 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ANKS6 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 50/479 reads (10%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO1 | c.1978C>A p.L660I | Missense Mutation (SNP) | VAF 39/266 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- APBA2 | c.773C>A p.P258H | Missense Mutation (SNP) | VAF 37/342 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ARFGEF3 | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1A | c.4555del p.Q1519Rfs*8 | Frame Shift Del (DEL) | VAF 23/228 reads (10%) | called by mutect2, pindel, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 37/380 reads (10%) | called by mutect2, varscan2
- ARID4A | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- ATAD2B | c.2127dup p.E710Rfs*11 | Frame Shift Ins (INS) | VAF 13/139 reads (9%) | called by mutect2, pindel
- ATM | c.8500T>G p.F2834V | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP4A | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- AXL | c.1555A>G p.S519G (on ENST00000301178 / NM_021913.5; = p.S510G on NM_001699.6) | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- BEND3 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BRD1 | c.2593G>A p.D865N (on ENST00000216267 / NM_001349940.1; = p.D996N on NM_001304808.3) | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- BRF1 | c.1101_1103del p.D367del | In Frame Del (DEL) | VAF 8/102 reads (8%) | called by mutect2, pindel
- BSN | c.3239A>G p.E1080G | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- C12orf40 | c.798A>G p.I266M | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.159); called by muse, mutect2
- CADM3 | c.317G>A p.G106D (on ENST00000368125 / NM_001127173.3; = p.G140D on NM_021189.5) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CAMSAP2 | c.4366G>A p.A1456T (on ENST00000236925 / NM_001297707.2; = p.A1445T on NM_203459.3) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- CAPN5 | c.185C>G p.A62G | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.935); called by muse, mutect2
- CASKIN2 | c.473T>G p.F158C | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC168 | c.11854A>G p.N3952D | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CCDC168 | c.10271del p.K3424Rfs*17 | Frame Shift Del (DEL) | VAF 17/202 reads (8%) | called by mutect2, pindel
- CDAN1 | c.216del p.A73Pfs*109 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by pindel, varscan2
- CDC42BPG | c.4627del p.L1543Yfs*14 | Frame Shift Del (DEL) | VAF 11/103 reads (11%) | called by mutect2, pindel, varscan2
- CDC42BPG | c.3277C>T p.P1093S | Missense Mutation (SNP) | VAF 29/300 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2
- CNOT3 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); called by muse, mutect2
- CNR1 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 47/315 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COA4 | c.235A>G p.R79G | Missense Mutation (SNP) | VAF 9/258 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- CYP2C18 | c.1102del p.H368Mfs*3 | Frame Shift Del (DEL) | VAF 19/143 reads (13%) | called by mutect2, pindel, varscan2
- DCHS1 | c.9379C>A p.P3127T | Missense Mutation (SNP) | VAF 21/271 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.081); called by muse, mutect2
- DGKZ | c.2147del p.F716Sfs*2 (on ENST00000454345 / NM_001105540.2; = p.F528Sfs*2 on NM_003646.4) | Frame Shift Del (DEL) | VAF 20/165 reads (12%) | called by mutect2, pindel, varscan2
- DMD | c.7619A>T p.K2540M | Missense Mutation (SNP) | VAF 25/271 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- DMRTC2 | c.171C>A p.H57Q | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.997); called by muse, mutect2
- DNAH10 | c.10428del p.D3477Mfs*54 (on ENST00000409039; = p.D3416Mfs*54 on NM_207437.3) | Frame Shift Del (DEL) | VAF 13/96 reads (14%) | called by mutect2, pindel, varscan2
- DNAH8 | c.232T>A p.S78T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, varscan2
- DNAJC5B | c.379T>C p.C127R | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.372); called by muse, mutect2
- E2F7 | c.1843A>G p.R615G | Missense Mutation (SNP) | VAF 58/360 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECHDC3 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ELFN2 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ELOA3 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 42/1608 reads (3%) | SIFT tolerated (0.6); PolyPhen benign (0.147); called by muse, mutect2
- EXOSC10 | c.536dup p.N179Kfs*14 | Frame Shift Ins (INS) | VAF 16/112 reads (14%) | called by mutect2, pindel, varscan2
- F5 | c.6128T>G p.I2043S | Missense Mutation (SNP) | VAF 25/360 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2
- FAM13C | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- FAM178B | c.1525C>T p.L509F | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- FLNA | c.1532G>A p.G511D | Missense Mutation (SNP) | VAF 52/752 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FSIP2 | c.19115del p.N6372Tfs*7 | Frame Shift Del (DEL) | VAF 9/101 reads (9%) | called by mutect2, pindel
- G6PD | c.121-2A>G p.X41_splice | Splice Site (SNP) | VAF 40/462 reads (9%) | called by muse, mutect2
- GFOD1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 44/412 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GLI1 | c.1700del p.P567Lfs*46 | Frame Shift Del (DEL) | VAF 17/171 reads (10%) | called by mutect2, pindel, varscan2
- GPATCH8 | c.564dup p.Q189Tfs*10 | Frame Shift Ins (INS) | VAF 25/172 reads (15%) | called by mutect2, pindel, varscan2
- GPR179 | c.2704G>A p.A902T (on ENST00000621958; = p.A901T on NM_001004334.4) | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2
- GRM5 | c.2443G>T p.G815C | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2
- GSG1 | c.326G>A p.G109D (on ENST00000651961 / NM_001080555.4; = p.G96D on NM_031289.5) | Missense Mutation (SNP) | VAF 41/376 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GUCY2D | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 10/317 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.108); called by muse, mutect2
- HCFC2 | c.926del p.N309Ifs*32 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, varscan2
- HSD11B1L | c.709del p.V237Cfs*26 | Frame Shift Del (DEL) | VAF 14/153 reads (9%) | called by mutect2, pindel, varscan2
- IFNE | c.454C>A p.H152N | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- IQCH | c.2222del p.X741_splice | Splice Site (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- KANK4 | c.1462A>C p.T488P | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- KCNA4 | c.1314G>A p.M438I | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.15); called by muse, varscan2
- KDM2A | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.304); called by muse, varscan2
- KMT2A | c.10591C>T p.P3531S | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); called by muse, mutect2
- KRT18 | c.355_357del p.K119del | In Frame Del (DEL) | VAF 30/284 reads (11%) | called by pindel, varscan2
- LCAT | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 65/510 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LIG4 | c.2203T>A p.F735I | Missense Mutation (SNP) | VAF 52/487 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- LOXHD1 | c.6636G>T p.E2212D (on ENST00000642948; = p.E2150D on NM_144612.7) | Missense Mutation (SNP) | VAF 98/834 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- LRRC42 | c.809T>A p.L270H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- LRRC66 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- MAGEB1 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- MAN1C1 | c.169del p.R57Gfs*125 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | called by mutect2, pindel
- MCPH1 | c.320_321del p.K107Tfs*2 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- MIPOL1 | c.49A>G p.T17A | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2
- MME | c.575A>T p.N192I | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- MTCL1 | c.2800C>A p.P934T (on ENST00000306329 / NM_001378206.1; = p.P574T on NM_015210.4) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYOG | c.553+1del p.X185_splice | Splice Site (DEL) | VAF 14/127 reads (11%) | called by mutect2, pindel, varscan2
- MYORG | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 69/507 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NAALADL1 | c.1267T>G p.S423A | Missense Mutation (SNP) | VAF 16/323 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NAPB | c.454T>C p.Y152H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NCAM1 | c.1232A>G p.E411G (on ENST00000316851 / NM_181351.5; = p.E401G on NM_000615.7) | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- NLRP1 | c.1765G>T p.D589Y | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- NOMO3 | c.682dup p.E228Gfs*17 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | called by mutect2, varscan2
- OR2H2 | c.698G>T p.R233M | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- OR4L1 | c.206del p.L69Wfs*13 | Frame Shift Del (DEL) | VAF 19/105 reads (18%) | called by mutect2, pindel, varscan2
- OR52B4 | c.892del p.T298Pfs*14 | Frame Shift Del (DEL) | VAF 13/96 reads (14%) | called by mutect2, pindel, varscan2
- PCDHB3 | c.1839dup p.L614Afs*150 | Frame Shift Ins (INS) | VAF 102/996 reads (10%) | called by mutect2, pindel
- PCSK7 | c.516G>T p.W172C | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PEX2 | c.310del p.I104Sfs*13 | Frame Shift Del (DEL) | VAF 57/301 reads (19%) | called by mutect2, pindel, varscan2
- PGGHG | c.267_270del p.L90Tfs*97 | Frame Shift Del (DEL) | VAF 43/328 reads (13%) | called by mutect2, pindel, varscan2
- PHLDB1 | c.2699del p.G900Afs*22 | Frame Shift Del (DEL) | VAF 26/299 reads (9%) | called by mutect2, pindel
- PKD1 | c.7209+2T>C p.X2403_splice | Splice Site (SNP) | VAF 83/717 reads (12%) | called by muse, mutect2, varscan2
- PKD2 | c.1450_1451del p.I484Lfs*41 | Frame Shift Del (DEL) | VAF 34/269 reads (13%) | called by mutect2, pindel, varscan2
- PPP6R1 | c.1651C>T p.Q551* | Nonsense Mutation (SNP) | VAF 39/273 reads (14%) | called by muse, mutect2, varscan2
- PPRC1 | c.2714C>A p.S905Y | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- PRKDC | c.5782G>A p.A1928T | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- PSD4 | c.688A>T p.T230S | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- RC3H2 | c.1567A>G p.K523E | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2
- REPS2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RSPH9 | c.650T>C p.L217S | Missense Mutation (SNP) | VAF 22/466 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RTBDN | c.465C>A p.T155= (on ENST00000393233 / NM_001270444.1; = p.T187= on NM_031429.2) | Splice Region (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.1032A>C p.R344S (on ENST00000265814 / NM_001198628.1; = p.R317S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.088); called by muse, mutect2
- SDHC | c.152C>A p.P51H | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC14L6 | c.785del p.G262Vfs*13 | Frame Shift Del (DEL) | VAF 26/220 reads (12%) | called by mutect2, varscan2
- SEC16A | c.6998T>C p.L2333P | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- SIX2 | c.687dup p.A230Rfs*103 | Frame Shift Ins (INS) | VAF 48/464 reads (10%) | called by mutect2, pindel, varscan2
- SLC22A12 | c.1367G>A p.S456N | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SLC26A5 | c.995A>C p.D332A | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.223); called by muse, mutect2
- SLC28A3 | c.13A>C p.S5R | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMARCA1 | c.779T>C p.V260A | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, mutect2
- SPATA48 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- SPATA5L1 | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2
- SPIB | c.353del p.P118Rfs*62 | Frame Shift Del (DEL) | VAF 9/106 reads (8%) | called by mutect2, pindel
- SRPX2 | c.83-1G>T p.X28_splice | Splice Site (SNP) | VAF 28/348 reads (8%) | called by muse, mutect2
- STMN3 | c.46T>A p.S16T | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, mutect2
- SUSD2 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- TAF1C | c.941A>G p.Y314C | Missense Mutation (SNP) | VAF 68/542 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- TANGO6 | c.2449C>T p.P817S | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- TBCD | c.2299C>A p.P767T | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TBXA2R | c.335T>A p.M112K | Missense Mutation (SNP) | VAF 67/531 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TCF20 | c.1552T>C p.S518P | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.04); called by muse, mutect2
- TFE3 | c.695A>T p.E232V | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- TLN1 | c.6898G>A p.D2300N | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2
- TLR1 | c.992del p.F331Sfs*30 | Frame Shift Del (DEL) | VAF 14/160 reads (9%) | called by mutect2, pindel
- TMEM175 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- TMEM82 | c.227A>G p.H76R | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.56); called by muse, mutect2
- TREH | c.251A>T p.E84V | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.152); called by muse, mutect2
- TRIM35 | c.449A>T p.N150I | Missense Mutation (SNP) | VAF 27/351 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TRIM64B | c.1156T>G p.Y386D | Missense Mutation (SNP) | VAF 50/955 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- TSPAN32 | c.83_84del p.V28Gfs*104 | Frame Shift Del (DEL) | VAF 20/151 reads (13%) | called by pindel, varscan2
- TSPEAR | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TXNDC11 | c.1568del p.L523* (on ENST00000356957 / NM_001303447.2; = p.L496* on NM_015914.7 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 42/350 reads (12%) | called by mutect2, pindel, varscan2
- UBA1 | c.2732A>G p.K911R | Missense Mutation (SNP) | VAF 56/487 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UNC45B | c.1369T>G p.F457V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UNC79 | c.2321G>A p.S774N (on ENST00000393151 / NM_001346218.2; = p.S597N on NM_020818.5) | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- VDR | c.1202A>G p.Y401C | Missense Mutation (SNP) | VAF 69/620 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- VPS35 | c.1647+2T>C p.X549_splice | Splice Site (SNP) | VAF 17/150 reads (11%) | called by muse, mutect2, varscan2
- WDR5 | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZFP91 | c.1490A>G p.E497G | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ZFPM2 | c.1645A>G p.T549A | Missense Mutation (SNP) | VAF 54/594 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF335 | c.202-2A>G p.X68_splice | Splice Site (SNP) | VAF 16/320 reads (5%) | called by muse, mutect2
- ZNF469 | c.8223G>T p.E2741D (on ENST00000437464; = p.E2769D on NM_001367624.2) | Missense Mutation (SNP) | VAF 54/650 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- ZNF560 | c.2233T>C p.C745R | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF658 | c.691A>G p.I231V | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- ACO2 | c.408C>T p.G136= | Silent (SNP) | VAF 32/317 reads (10%) | catalogued as rs543394003, COSV99347383; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM8 | c.483G>A p.L161= | Silent (SNP) | VAF 27/336 reads (8%) | catalogued as rs375923416; called by muse, mutect2
- ADARB1 | c.2139G>A p.A713= (on ENST00000360697 / NM_001346687.2; = p.A673= on NM_001112.4) | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as rs768328836, COSV100653575; called by muse, mutect2, varscan2
- AKAP1 | c.1602G>A p.P534= | Silent (SNP) | VAF 25/360 reads (7%) | catalogued as rs372374542; called by muse, mutect2
- ANKMY1 | c.1551G>A p.A517= | Silent (SNP) | VAF 30/258 reads (12%) | catalogued as rs756574770, COSV56035569; called by muse, mutect2, varscan2
- AR | c.414C>A p.A138= | Silent (SNP) | VAF 24/253 reads (9%) | catalogued as rs776441367; called by muse, mutect2
- ARHGEF11 | c.804G>A p.R268= | Silent (SNP) | VAF 25/206 reads (12%) | called by muse, mutect2, varscan2
- ATG2A | c.3048G>A p.Q1016= | Silent (SNP) | VAF 64/620 reads (10%) | called by muse, mutect2
- B3GALT5 | c.504A>G p.E168= | Silent (SNP) | VAF 26/262 reads (10%) | called by muse, mutect2
- CACNA1B | c.597C>A p.P199= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as rs199818961; called by muse, mutect2, varscan2
- CAPZB | c.612T>C p.S204= | Silent (SNP) | VAF 18/136 reads (13%) | called by muse, varscan2
- CARD6 | c.2832C>T p.S944= | Silent (SNP) | VAF 34/354 reads (10%) | catalogued as rs756642764; called by muse, mutect2
- CARD8 | c.1497T>C p.N499= (on ENST00000651546 / NM_001184900.3; = p.N449= on NM_014959.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 13/213 reads (6%) | called by muse, mutect2
- CBFA2T3 | c.864C>T p.N288= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as rs1212665439, COSV51924195; called by muse, mutect2, varscan2
- CCDC43 | c.336A>G p.Q112= | Silent (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- CEP72 | c.1755G>A p.T585= | Silent (SNP) | VAF 16/164 reads (10%) | catalogued as rs142569661; called by muse, mutect2, varscan2
- CGB1 | c.276C>T p.R92= | Silent (SNP) | VAF 33/402 reads (8%) | catalogued as rs775748503; called by muse, mutect2, varscan2
- CHST8 | c.297G>T p.L99= | Silent (SNP) | VAF 26/243 reads (11%) | called by muse, mutect2, varscan2
- CR2 | c.2898G>A p.A966= | Silent (SNP) | VAF 25/236 reads (11%) | catalogued as rs748861832, COSV65506085; called by muse, mutect2, varscan2
- CRISP3 | c.402A>G p.S134= (on ENST00000371159 / NM_001368123.1; = p.S116= on NM_006061.4) | Silent (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- CSMD3 | c.6063G>A p.T2021= (on ENST00000297405 / NM_001363185.1; = p.T1917= on NM_052900.3) | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as rs150436177, COSV52368262; called by muse, mutect2, varscan2
- DKKL1 | c.573C>T p.S191= | Silent (SNP) | VAF 24/197 reads (12%) | catalogued as rs375202437, COSV55561777; called by muse, mutect2, varscan2
- DMRTB1 | c.213G>A p.A71= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as rs1315212618; called by muse, mutect2, varscan2
- DNAH1 | c.8019C>T p.D2673= | Silent (SNP) | VAF 26/340 reads (8%) | catalogued as rs759999285, COSV70227608; called by muse, mutect2
- DOK1 | c.405T>C p.L135= | Silent (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
- DUSP13 | c.327T>C p.S109= | Silent (SNP) | VAF 43/325 reads (13%) | called by muse, mutect2, varscan2
- DUSP3 | c.297C>T p.S99= | Silent (SNP) | VAF 21/229 reads (9%) | called by muse, mutect2
- EIF2D | c.921G>T p.L307= | Silent (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- EPHX2 | c.763C>T p.L255= | Silent (SNP) | VAF 25/322 reads (8%) | called by muse, mutect2
- EVC | c.456G>A p.P152= | Silent (SNP) | VAF 52/588 reads (9%) | catalogued as rs776773987, COSV99382827; called by muse, mutect2
- F2RL2 | c.726C>T p.I242= | Silent (SNP) | VAF 56/491 reads (11%) | catalogued as rs1014141727; called by muse, mutect2, varscan2
- FAM104B | c.30A>G p.R10= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- FBN2 | c.3162C>T p.R1054= | Silent (SNP) | VAF 24/433 reads (6%) | catalogued as rs765015874, COSV52526134; ClinVar: uncertain significance; called by muse, mutect2
- FBXL18 | c.2079C>T p.D693= | Silent (SNP) | VAF 22/158 reads (14%) | catalogued as rs781480435; called by muse, varscan2
- FCAMR | c.678C>T p.A226= | Silent (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2
- FCGBP | c.11919T>C p.C3973= | Silent (SNP) | VAF 88/456 reads (19%) | called by muse, mutect2, varscan2
- FHOD3 | c.1719G>A p.A573= (on ENST00000359247 / NM_001281739.3; = p.A590= on NM_025135.5) | Silent (SNP) | VAF 22/155 reads (14%) | catalogued as rs776503779; called by muse, mutect2, varscan2
- FSCB | c.1272T>G p.V424= | Silent (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2, varscan2
- GAD2 | c.1110A>G p.G370= | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- GRAMD1B | c.1413C>T p.D471= | Silent (SNP) | VAF 18/310 reads (6%) | catalogued as rs1301385664, COSV59200091; called by muse, mutect2
- HEMGN | c.1053C>T p.D351= | Silent (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- INF2 | c.1755G>A p.A585= | Silent (SNP) | VAF 20/174 reads (11%) | catalogued as rs375573206; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- ITPK1 | c.312T>C p.L104= | Silent (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- ITSN2 | c.4608G>A p.V1536= | Silent (SNP) | VAF 14/143 reads (10%) | catalogued as rs143298177; called by muse, mutect2, varscan2
- KLC2 | c.723C>T p.T241= | Silent (SNP) | VAF 34/309 reads (11%) | called by muse, mutect2, varscan2
- KLF1 | c.99C>T p.S33= | Silent (SNP) | VAF 27/142 reads (19%) | called by muse, mutect2, varscan2
- LGR6 | c.612C>T p.Y204= (on ENST00000367278 / NM_001017403.1; = p.Y152= on NM_021636.3) | Silent (SNP) | VAF 27/218 reads (12%) | catalogued as rs776399629; called by muse, mutect2, varscan2
- LIMK2 | c.1890C>T p.Y630= | Silent (SNP) | VAF 23/181 reads (13%) | catalogued as rs1228268732; called by muse, mutect2, varscan2
- LIN7B | c.555C>T p.F185= | Silent (SNP) | VAF 21/164 reads (13%) | catalogued as rs750667237, COSV55522120; called by muse, mutect2, varscan2
- LLGL2 | c.2568C>T p.A856= | Silent (SNP) | VAF 34/312 reads (11%) | catalogued as rs758645564, COSV51375790; called by muse, mutect2, varscan2
- LRRC10 | c.759G>A p.R253= | Silent (SNP) | VAF 28/350 reads (8%) | called by muse, mutect2
- LRRC45 | c.690G>A p.R230= | Silent (SNP) | VAF 16/263 reads (6%) | called by muse, mutect2
- LTN1 | c.4020T>C p.N1340= | Silent (SNP) | VAF 25/166 reads (15%) | called by muse, mutect2, varscan2
- MAGEC1 | c.2634T>C p.Y878= | Silent (SNP) | VAF 24/289 reads (8%) | catalogued as COSV53582181; called by muse, mutect2
- MAP4K4 | c.195A>G p.E65= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- MAPK4 | c.1122C>T p.D374= | Silent (SNP) | VAF 19/173 reads (11%) | catalogued as COSV68541207; called by muse, mutect2, varscan2
- MCM3 | c.1446G>A p.Q482= (on ENST00000229854 / NM_001366374.2; = p.Q472= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- MLYCD | c.858G>A p.A286= | Silent (SNP) | VAF 57/501 reads (11%) | catalogued as rs369708416, COSV52305735; called by muse, mutect2, varscan2
- MRGPRF | c.126G>A p.P42= | Silent (SNP) | VAF 28/233 reads (12%) | called by muse, mutect2, varscan2
- MTG1 | c.159C>T p.I53= | Silent (SNP) | VAF 15/240 reads (6%) | catalogued as rs757542743; called by muse, mutect2
- MUC4 | c.14776C>T p.L4926= (on ENST00000463781 / NM_018406.7; = p.L690= on NM_004532.6) | Silent (SNP) | VAF 41/382 reads (11%) | called by muse, mutect2, varscan2
- MUC4 | c.13356G>A p.T4452= (on ENST00000463781 / NM_018406.7; = p.T216= on NM_004532.6) | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as rs149702313; called by muse, mutect2, varscan2
- MX2 | c.2106G>A p.A702= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as rs143528488; called by muse, mutect2, varscan2
- MXRA5 | c.2145G>A p.L715= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV54231888; called by muse, mutect2
- MYO16 | c.162G>A p.P54= | Silent (SNP) | VAF 36/319 reads (11%) | catalogued as rs372620045; called by muse, mutect2, varscan2
- NCBP1 | c.2244G>A p.Q748= | Silent (SNP) | VAF 39/400 reads (10%) | called by muse, mutect2
- NCLN | c.711C>T p.G237= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as rs368717040; called by muse, mutect2, varscan2
- OR2A12 | c.699C>T p.R233= | Silent (SNP) | VAF 42/431 reads (10%) | catalogued as rs1388151973; called by muse, mutect2
- OR2A5 | c.330T>C p.T110= | Silent (SNP) | VAF 34/477 reads (7%) | called by muse, mutect2
- OR51E1 | c.597C>T p.V199= | Silent (SNP) | VAF 35/246 reads (14%) | catalogued as rs760197684; called by muse, mutect2, varscan2
- OR51Q1 | c.99C>T p.V33= | Silent (SNP) | VAF 24/217 reads (11%) | called by muse, mutect2, varscan2
- ORM2 | c.102C>T p.A34= | Silent (SNP) | VAF 26/221 reads (12%) | catalogued as rs770023761; called by muse, mutect2, varscan2
- PBOV1 | c.60A>G p.L20= | Silent (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- PCDHA8 | c.1362G>A p.A454= | Silent (SNP) | VAF 41/875 reads (5%) | catalogued as COSV65337296; called by muse, mutect2
- PCDHAC1 | c.1518C>A p.A506= | Silent (SNP) | VAF 16/271 reads (6%) | called by muse, mutect2
- PCDHGB5 | c.1332C>T p.N444= | Silent (SNP) | VAF 35/311 reads (11%) | called by muse, mutect2, varscan2
- PCP2 | c.96C>T p.H32= | Silent (SNP) | VAF 25/201 reads (12%) | catalogued as rs150461106; called by muse, mutect2, varscan2
- PEX1 | c.3243G>A p.L1081= | Silent (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- PGBD5 | c.675C>T p.G225= (on ENST00000525115; = p.G294= on NM_001258311.2) | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as rs776683374; called by muse, mutect2
- PLEKHM2 | c.1173G>A p.P391= | Silent (SNP) | VAF 23/222 reads (10%) | catalogued as rs376636032; called by muse, mutect2, varscan2
- PMFBP1 | c.1068C>T p.D356= | Silent (SNP) | VAF 13/158 reads (8%) | catalogued as COSV99400755; called by muse, mutect2
- PPFIA4 | c.3486G>A p.P1162= (on ENST00000447715; = p.P1163= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV55313830; called by muse, mutect2, varscan2
- PRRC2B | c.2964C>T p.D988= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as rs566578338, COSV100621819; called by muse, mutect2, varscan2
- PTGIR | c.360G>A p.A120= | Silent (SNP) | VAF 17/204 reads (8%) | catalogued as rs1186818411; called by muse, mutect2
- RAI1 | c.1083G>A p.S361= | Silent (SNP) | VAF 60/505 reads (12%) | catalogued as rs981995746, COSV55399458; called by muse, mutect2, varscan2
- RPS16 | c.18G>A p.P6= | Silent (SNP) | VAF 20/232 reads (9%) | catalogued as rs1251567946; called by muse, mutect2
- RYR3 | c.4698C>T p.S1566= | Silent (SNP) | VAF 27/173 reads (16%) | catalogued as rs563422149, COSV66803441; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCP2D1 | c.333G>A p.P111= | Silent (SNP) | VAF 31/211 reads (15%) | catalogued as rs368734818, COSV53857071; called by muse, mutect2, varscan2
- SEMA5B | c.2763A>G p.P921= | Silent (SNP) | VAF 24/176 reads (14%) | called by muse, varscan2
- SH2B1 | c.348C>A p.P116= | Silent (SNP) | VAF 17/211 reads (8%) | called by muse, mutect2
- SHOX | c.201G>A p.P67= | Silent (SNP) | VAF 16/250 reads (6%) | catalogued as rs753509357; called by muse, mutect2
- SLC52A2 | c.777C>T p.G259= | Silent (SNP) | VAF 102/489 reads (21%) | catalogued as rs1554854195; called by muse, mutect2, varscan2
- SP5 | c.864G>A p.A288= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV64623616; called by muse, mutect2, varscan2
- SPEN | c.8241T>C p.T2747= | Silent (SNP) | VAF 36/327 reads (11%) | called by muse, mutect2, varscan2
- SPSB4 | c.162C>T p.H54= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs1342954232; called by muse, mutect2, varscan2
- STK11 | c.828C>T p.G276= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as rs200824447; ClinVar: likely benign; called by muse, mutect2, varscan2
- TENM3 | c.7761C>T p.N2587= | Silent (SNP) | VAF 24/248 reads (10%) | catalogued as COSV101305286, COSV69306153; called by muse, mutect2
- TFAP2A | c.834G>A p.L278= (on ENST00000482890; = p.L270= on NM_001032280.3) | Silent (SNP) | VAF 25/262 reads (10%) | catalogued as COSV100116833; called by muse, mutect2
- TFDP1 | c.501G>A p.R167= | Silent (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- TMCC2 | c.246C>T p.H82= | Silent (SNP) | VAF 27/227 reads (12%) | catalogued as rs78982342, COSV100788397; called by muse, mutect2, varscan2
- TMEM11 | c.519G>A p.T173= | Silent (SNP) | VAF 21/165 reads (13%) | catalogued as rs765996667, COSV58313223; called by muse, mutect2, varscan2
- TMEM61 | c.510C>T p.P170= | Silent (SNP) | VAF 47/380 reads (12%) | catalogued as rs145882409, COSV100987758; called by muse, mutect2, varscan2
- TPCN2 | c.2175G>T p.L725= | Silent (SNP) | VAF 36/229 reads (16%) | called by muse, mutect2, varscan2
- TSC2 | c.1401C>T p.D467= | Silent (SNP) | VAF 18/487 reads (4%) | catalogued as rs1433989426; ClinVar: likely benign; called by muse, mutect2
- TSHZ1 | c.1893G>A p.P631= (on ENST00000580243 / NM_001308210.2; = p.P586= on NM_005786.6) | Silent (SNP) | VAF 23/236 reads (10%) | catalogued as rs145239521; called by muse, mutect2
- TTN | c.56538C>T p.T18846= (on ENST00000591111; = p.T11422= on NM_003319.4) | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs769161030; called by muse, mutect2, varscan2
- TUBG1 | c.1146C>A p.T382= | Silent (SNP) | VAF 23/146 reads (16%) | called by muse, mutect2, varscan2
- TYR | c.237G>A p.S79= | Silent (SNP) | VAF 34/510 reads (7%) | catalogued as rs376813190; called by muse, mutect2
- UNC5C | c.2490G>A p.A830= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as rs762675647, COSV71658933; called by muse, mutect2, varscan2
- URB2 | c.3366G>A p.T1122= | Silent (SNP) | VAF 20/186 reads (11%) | catalogued as rs1339870048, COSV50982923; called by muse, mutect2
- VIPR1 | c.1278C>T p.N426= | Silent (SNP) | VAF 13/221 reads (6%) | catalogued as rs1215739211; called by muse, mutect2
- WDR19 | c.3672C>T p.S1224= | Silent (SNP) | VAF 37/405 reads (9%) | catalogued as rs1324193132; called by muse, mutect2
- WRN | c.1701T>C p.N567= | Silent (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- ZDHHC5 | c.1557G>A p.V519= | Silent (SNP) | VAF 28/351 reads (8%) | catalogued as rs1185698020; called by muse, mutect2
- ZNF518B | c.2037G>A p.P679= | Silent (SNP) | VAF 25/340 reads (7%) | catalogued as rs759322328, COSV58721986; called by muse, mutect2
- ZNF668 | c.450C>T p.G150= | Silent (SNP) | VAF 20/200 reads (10%) | catalogued as rs765786681; called by muse, mutect2, varscan2
- ZNF8 | c.282C>T p.C94= | Silent (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2, varscan2
- AC020907.6 | c.-598C>T | 5'UTR (SNP) | VAF 63/546 reads (12%) | catalogued as rs374996780; called by muse, mutect2, varscan2
- AC092818.1 | n.252T>C | RNA (SNP) | VAF 40/364 reads (11%) | catalogued as rs1478165984; called by muse, mutect2, varscan2
- AC098591.2 | n.758G>A | RNA (SNP) | VAF 59/545 reads (11%) | called by muse, mutect2, varscan2
- AC116366.2 | c.-637-10323dup | Intron (INS) | VAF 40/316 reads (13%) | catalogued as rs967031683; called by mutect2, pindel, varscan2
- AGA | c.*39_*42del | 3'UTR (DEL) | VAF 32/254 reads (13%) | catalogued as rs1420988245; called by pindel, varscan2
- AL353804.4 | chrX:73822434 del T | 5'Flank (DEL) | VAF 28/308 reads (9%) | called by mutect2, pindel
- ATP13A2 | c.1542+48C>T | Intron (SNP) | VAF 67/533 reads (13%) | catalogued as rs759228756; called by muse, mutect2, varscan2
- ATP6AP1L | n.1763G>A | RNA (SNP) | VAF 36/286 reads (13%) | catalogued as rs369765030; called by muse, mutect2, varscan2
- AVIL | c.66+396_66+397del | Intron (DEL) | VAF 10/82 reads (12%) | called by pindel, varscan2
- C1orf112 | c.-2A>G | 5'UTR (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- CD164L2 | c.328+62dup | Intron (INS) | VAF 43/397 reads (11%) | catalogued as rs756775166; called by mutect2, pindel, varscan2
- CD1A | c.*42T>C | 3'UTR (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2, varscan2
- CD99L2 | c.*60del | 3'UTR (DEL) | VAF 5/25 reads (20%) | catalogued as COSV100692596; called by mutect2, pindel, varscan2
- CDIPT | chr16:29864314 T>C | 5'Flank (SNP) | VAF 13/162 reads (8%) | called by muse, mutect2
- CEROX1 | n.2880G>A | RNA (SNP) | VAF 67/636 reads (11%) | catalogued as rs375744448; called by muse, mutect2, varscan2
- CFB | c.-22T>C | 5'UTR (SNP) | VAF 17/684 reads (2%) | called by muse, mutect2
- COMMD4 | c.75+46del | Intron (DEL) | VAF 26/245 reads (11%) | catalogued as rs776968453; called by mutect2, varscan2
- COX6A1P2 | n.65G>A | RNA (SNP) | VAF 30/474 reads (6%) | catalogued as rs1254480886; called by muse, mutect2
- CPSF4 | c.*30G>A | 3'UTR (SNP) | VAF 40/440 reads (9%) | catalogued as rs199965995, COSV99461680; called by muse, mutect2
- CRELD1 | c.460+41C>T | Intron (SNP) | VAF 34/246 reads (14%) | catalogued as rs765996826; called by muse, mutect2, varscan2
- DAPK3 | c.*582G>A | 3'UTR (SNP) | VAF 11/160 reads (7%) | catalogued as rs1054731145; called by muse, mutect2
- DCBLD2 | c.571+70del | Intron (DEL) | VAF 7/62 reads (11%) | catalogued as rs780707032; called by mutect2, pindel, varscan2
- DDX24 | c.2179-9T>C | Intron (SNP) | VAF 23/171 reads (13%) | catalogued as rs1328539040; called by muse, mutect2, varscan2
- DHDDS | c.766-1557C>T | Intron (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- EGFEM1P | n.719C>T | RNA (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- EGFLAM | c.2796-18del | Intron (DEL) | VAF 10/91 reads (11%) | called by mutect2, pindel, varscan2
- EIPR1 | c.516+5307C>A | Intron (SNP) | VAF 32/275 reads (12%) | called by muse, mutect2, varscan2
- FAM107A | c.88+2343G>A | Intron (SNP) | VAF 8/65 reads (12%) | catalogued as rs1027089614; called by muse, mutect2, varscan2
- FBXL21P | n.1232G>A | RNA (SNP) | VAF 52/424 reads (12%) | catalogued as rs772421860, COSV99778490; called by muse, mutect2, varscan2
- FKBP6 | c.-23G>A | 5'UTR (SNP) | VAF 28/323 reads (9%) | catalogued as rs782583942, COSV99334198; called by muse, mutect2
- FOXP1 | c.1146+32del | Intron (DEL) | VAF 12/105 reads (11%) | called by mutect2, pindel, varscan2
- GP6 | c.*805del | 3'UTR (DEL) | VAF 22/244 reads (9%) | catalogued as rs1449880088; called by mutect2, pindel
- HDAC2 | c.-189A>G | 5'UTR (SNP) | VAF 19/163 reads (12%) | catalogued as rs1016833113, COSV64037794; called by muse, mutect2, varscan2
- HLA-DOA | c.*71G>A | 3'UTR (SNP) | VAF 26/164 reads (16%) | catalogued as rs770807497; called by muse, mutect2, varscan2
- JPH3 | c.2167-760G>A | Intron (SNP) | VAF 26/438 reads (6%) | catalogued as rs759512067, COSV99413619; called by muse, mutect2
- KCNQ3 | c.386+32938C>T | Intron (SNP) | VAF 24/145 reads (17%) | catalogued as rs552538402, COSV66480363; called by muse, mutect2, varscan2
- KIFC3 | c.*281C>A | 3'UTR (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- KLHDC4 | c.99+516T>C | Intron (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2, varscan2
- KMT5C | c.570+1057del | Intron (DEL) | VAF 18/144 reads (13%) | catalogued as rs761097492; called by mutect2, varscan2
- KPNB1 | c.*4G>T | 3'UTR (SNP) | VAF 14/143 reads (10%) | called by muse, mutect2
- LINC01548 | n.317T>C | RNA (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- LTN1 | c.2163+1199G>A | Intron (SNP) | VAF 12/141 reads (9%) | catalogued as rs1264626199, COSV63735040; called by muse, mutect2
- MAGED2 | c.1272-270dup | Intron (INS) | VAF 31/205 reads (15%) | called by mutect2, pindel, varscan2
- MAGI3 | c.3329-628A>G | Intron (SNP) | VAF 4/38 reads (11%) | catalogued as rs900713715; called by mutect2, varscan2
- MAST1 | c.*21G>A | 3'UTR (SNP) | VAF 18/152 reads (12%) | catalogued as rs777634353; called by muse, mutect2, varscan2
- MIR29B2CHG | n.299A>G | RNA (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- NBPF11 | c.-548-2993G>A | Intron (SNP) | VAF 34/438 reads (8%) | called by muse, mutect2
- NRXN1 | c.772+1063C>T | Intron (SNP) | VAF 6/61 reads (10%) | catalogued as rs184695687; ClinVar: uncertain significance; called by mutect2, varscan2
- NXF5 | n.818T>A | RNA (SNP) | VAF 37/317 reads (12%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2856del | Intron (DEL) | VAF 29/267 reads (11%) | catalogued as rs1269000314; called by mutect2, varscan2
- PABPC4 | c.1405+11G>T | Intron (SNP) | VAF 17/167 reads (10%) | called by muse, mutect2, varscan2
- PCDHA5 | c.2352+77del | Intron (DEL) | VAF 11/101 reads (11%) | catalogued as rs781996539; called by mutect2, pindel, varscan2
- PCDHB6 | chr5:141156187 C>A | 3'Flank (SNP) | VAF 20/184 reads (11%) | catalogued as rs781847433; called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157134 ins A | 3'Flank (INS) | VAF 37/355 reads (10%) | called by mutect2, pindel, varscan2
- PDE6H | c.-17G>A | 5'UTR (SNP) | VAF 8/70 reads (11%) | catalogued as rs370234224, COSV56761530; called by mutect2, varscan2
- PPY | chr17:43938593 C>T | 3'Flank (SNP) | VAF 13/132 reads (10%) | catalogued as rs1198054753; called by muse, mutect2
- QKI | c.935-53del | Intron (DEL) | VAF 10/100 reads (10%) | catalogued as rs372217972; called by mutect2, pindel, varscan2
- RASEF | c.431+6887G>A | Intron (SNP) | VAF 19/121 reads (16%) | catalogued as rs536098072; called by muse, mutect2, varscan2
- RHOT1 | c.1739+1049A>G | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- RICTOR | c.753+38T>C | Intron (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- RPL7A | c.495+129C>T | Intron (SNP) | VAF 41/300 reads (14%) | catalogued as rs55880012; called by muse, mutect2, varscan2
- RPS11 | c.223+133_223+135del | Intron (DEL) | VAF 32/322 reads (10%) | catalogued as rs1235398742; called by pindel, varscan2
- SCD5 | c.569+19699G>A | Intron (SNP) | VAF 36/336 reads (11%) | catalogued as COSV56725724; called by muse, mutect2, varscan2
- SLC22A3 | c.*7C>T | 3'UTR (SNP) | VAF 20/260 reads (8%) | catalogued as rs751885139, COSV99278160; called by muse, mutect2
- SMARCC1 | c.*26G>A | 3'UTR (SNP) | VAF 5/48 reads (10%) | catalogued as rs767843750, COSV99592870; called by mutect2, varscan2
- SNORD115-1 | n.2T>C | RNA (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- SPTBN2 | c.5566-43T>C | Intron (SNP) | VAF 9/80 reads (11%) | catalogued as rs1243408585; called by mutect2, varscan2
- STAB1 | c.4762-3del | Intron (DEL) | VAF 18/180 reads (10%) | catalogued as rs753921792; called by mutect2, pindel
- TCOF1 | c.2859+18T>C | Intron (SNP) | VAF 20/728 reads (3%) | called by muse, mutect2
- TG | c.1075+29C>T | Intron (SNP) | VAF 22/227 reads (10%) | catalogued as rs1307328930, COSV55085740; called by muse, mutect2, varscan2
- TMCO1 | c.*2158T>C | 3'UTR (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- TXNRD3 | n.875C>T | RNA (SNP) | VAF 21/214 reads (10%) | catalogued as rs767089243; called by muse, mutect2
- UBQLN2 | c.*26del | 3'UTR (DEL) | VAF 20/187 reads (11%) | catalogued as rs745344524; called by mutect2, varscan2
- UNC13D | c.1849-41dup | Intron (INS) | VAF 45/425 reads (11%) | called by mutect2, pindel
- UQCRB | c.91+29dup | Intron (INS) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- WDR86 | c.*57C>T | 3'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
